Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A631, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A631-01A (Primary Tumor).

[page 1 of 3]
Report for [REDACTED]

TEST: Surgical Pathology
Collected Date & Time: [REDACTED]

Result Name Results Units
Surgical Pathology
SURGICAL PATHOLOGY REPORT

Reference Range

path ICD-O-3
Adenocarcinoma NOS 8140/3
C&F *Adenocarcinoma, acinar* 8140/3
Site: Prostate NOS C61.9
JW 5/10/13

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec. #: [REDACTED]
Billing Type:
Location:
DOB: (Age: [REDACTED])
Service: [REDACTED]
Gender: M
Billing: [REDACTED]
Taken Received Reported:
Physician(s): [REDACTED]

Specimen(s) Received

A: Right external iliac and obturator lymph nodes
B: Prostate

Pathologic Diagnosis

Lymph nodes, right external iliac and obturator, excision (A):
- 2 lymph nodes, negative for malignancy (0/2).

Prostate, excision (B):
- Prostatic adenocarcinoma, Gleason score 4+5=9.
- High-grade prostatic intraepithelial neoplasia.

Note: The prostatic adenocarcinoma is centered in the right lobe of the prostate and demonstrates a majority of Gleason 4 pattern with a secondary Gleason 5 pattern. Focally, the right posterior lateral margin of the prostate is involved by adenocarcinoma. Along the posterior and posterolateral margins on the right side, the tumor is present within a fraction of a millimeter of the inked margin of excision.

SURGICAL PATHOLOGY CANCER CASE SUMMARY CHECKLIST: PROSTATE GLAND, RADICAL PROSTATECTOMY

Procedure: Radical prostatectomy
Prostate Size:

Weight: 34 g
Size: 4.0 x 3.5 x 3.3 cm

Lymph Node Sampling: Pelvic lymph node dissection
Histologic Type: Adenocarcinoma, acinar, NOS
Histologic Grade/Gleason Pattern:

Primary Pattern: Grade 4
Secondary Pattern: Grade 5
Tertiary Pattern: Grade 3
Total Gleason Score: 4+5=9

Tumor Quantitation:

Proportion of prostate involved by tumor: Approximately 40%
Extraprostatic Extension: Not identified
Seminal Vesicle Invasion: Not identified
Margins: Margins involved by invasive carcinoma, unifocal, right posterolateral

[page 2 of 3]
Treatment Effect on Carcinoma: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Present
Pathologic Staging:

Primary Tumor: pT2c

Regional lymph nodes: pN0

Number of lymph nodes examined: 2

Number of lymph nodes involved: 0

Distant metastasis: Not applicable

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

Primary Pathologist:

Electronically Signed Out by:

Clinical History

Prostate cancer, additional information is provided.

Intraoperative Consultation

A. Right external iliac obturator lymph nodes: Four benign lymph nodes. (microscopic evaluation)
Ph.D.

Gross Description

A. Received fresh for frozen section labeled "right external iliac obturator lymph nodes" is a 6.0 x 5.0 x 1.0 cm aggregate of fat. There are four lymph nodes dissected out, ranging from 0.7 to 4.5 cm in greatest dimension. The lymph nodes are submitted as follows:

A1FS - 4.5 cm lymph node inked black and bisected.

A2FS - three lymph nodes (one orange, one yellow, one blue).

B. Received in formalin labeled "prostate" is a 34 g, 4.0 cm from left to right, 3.3 cm from anterior to posterior, 3.5 cm from apex to bladder neck margin prostatectomy specimen with attached right seminal vesicle (4.0 x 1.4 x 0.3 cm), right vas deferens (3.2 x 0.5 x 0.4 cm), left seminal vesicle (3.2 x 1.7 x 0.6 cm), left vas deferens (3.0 x 0.5 x 0.4 cm). The prostate is inked as follows: right prostate is inked blue, left prostate is inked black, and bladder neck margin is inked yellow.

The prostate is serially sectioned from apex to bladder neck margin to reveal a 2.2 cm in greatest dimension firm white-tan lesion located in the right anterior and right posterior prostate that extends from apex to bladder neck margin. The lesion grossly approaches the apex margin. There are no other discrete nodules or masses grossly identified. 85% of the specimen is submitted in cassettes B1 through B20. Sections are submitted as follows:

B1, B2 - right apex perpendicularly cut.

B3, B4 - left apex perpendicularly cut.

B5, B6 - right bladder neck margin perpendicularly cut.

B7, B8 - left bladder neck margin perpendicularly cut.

B9 - right seminal vesicle insertion point and cross-section

[page 3 of 3]
through right seminal vesicle and vas deferens.
B10 - left seminal vesicle insertion point and cross-section
through left seminal vesicle and vas deferens.
B11 - right anterior prostate.
B12-B15 - right posterior prostate from apex to bladder neck
margin.
B16 - left anterior prostate.
B17-B20 - left posterior prostate from apex to bladder neck
margin.
[REDACTED]

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Interpretation performed at [REDACTED]

If immunohistochemistry or in situ hybridization was used the following applies: This test was developed and its performance characteristic determined by [REDACTED] It has not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA does not require this test to go through premarket FDA review. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing. All special stains used have adequate controls.

Reviewed Initials:	[Signature] 4/11/13	

Source: NCI Genomic Data Commons file 1da670ff-1851-4c01-8646-60cecb896f22 (TCGA-HC-A631.70585F33-CB9E-4365-9CA2-E384BED102DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).